Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A465, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A465-01A (Primary Tumor).

[page 1 of 4]
M

Accession:
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LINGUAL NERVE SEGMENT:

Nerve, negative for tumor.

(B) RIGHT PARTIAL GLOSSECTOMY:

INVASIVE SQUAMOUS CARCINOMA -- Well differentiated

Tumor Features:

Gross: Ulcerating

Size: 2.8 cm in largest dimension

Invasion: Present, depth 1.3 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: Present, Focal

Vascular Invasion: Absent

ICD-O-3
Carcinoma, squamous cell, NOS 8070/3
Site: tongue, NOS C02.9

(C) DORSAL TONGUE MARGIN:

Squamous mucosa, negative for tumor.

(D) ANTERIOR TONGUE MARGIN:

Squamous mucosa, negative for tumor.

(E) VENTRAL TONGUE MARGIN:

Squamous mucosa, negative for tumor.

(F) ANTERIOR FLOOR OF MOUTH MARGIN:

Squamous mucosa and salivary tissue negative for tumor.

(G) POSTERIOR FLOOR OF MOUTH MARGIN:

Squamous mucosa and salivary tissue, negative for tumor.

(H) POSTERIOR TONGUE MARGIN:

Squamous mucosa negative for tumor.

(I) DEEP TONGUE MARGIN:

Skeletal muscle, negative for tumor.

(J) RIGHT NECK DISSECTION, LEVELS I "A" AND "B":

Seven lymph nodes, negative for tumor (0/7).

Benign salivary gland.

(K) RIGHT NECK DISSECTION, LEVEL II:

Sixteen lymph nodes, negative for tumor (0/16).

(L) RIGHT NECK DISSECTION, LEVEL III:

Nine lymph nodes, negative for tumor (0/9).

(M) RIGHT NECK DISSECTION, LEVEL IV:

Twenty-one lymph nodes, negative for tumor (0/21).

W
10/1/12

[page 2 of 4]
Accession:
Specimen Date/Time:

- (N) MULTIPLE DENTAL EXTRACTIONS WITH BONE AND SOFT TISSUE:
Multiple teeth and tooth fragments (gross examination only)

GROSS DESCRIPTION

- (A) LINGUAL NERVE SEGMENT, FROZEN - Received fresh is a pink-tan tissue segment without orientation measuring 0.2 x 0.2 x 0.2 cm. Entirely submitted in A, for frozen.
*FS/DX: NEGATIVE.
- (B) RIGHT PARTIAL GLOSSECTOMY - An elliptical portion of mucosa and underlying soft tissue (3.4 x 2.0 x 1.5 cm) is oriented with a long stitch for anterior and a short stitch for floor of mouth. The mucosa is disrupted by an ulcer (1.0 x 0.8 cm) centrally corresponding to a tumor which fills the majority of the specimen (2.8 x 1.1 x 1.3 cm deep). Grossly the tumor extends to within 2 mm of the deep soft tissue near the anterior floor of mouth on this specimen.
SECTION CODE: B1-B7, serially sectioned and entirely submitted from anterior-to-posterior (blue designates tongue side for orientation only).
- (C) DORSAL TONGUE MARGIN, NEW MARGIN INKED - Received is a pink-tan (2.5 x 0.3 x 0.2 cm) fragment of the specimen with ink. The margin is reinked and entirely submitted in C, for frozen section.
*FS/DX: NEGATIVE.
- (D) ANTERIOR TONGUE, NEW MARGIN INKED, FROZEN - Received fresh is a pink-tan tissue fragment (1.9 x 0.2 x 0.2 cm) with ink. The margin is reinked and entirely submitted in D.
*FS/DX: NEGATIVE.
- (E) VENTRAL TONGUE, NEW MARGIN INKED, FROZEN - Received fresh is a pink-tan tissue fragment (1.5 x 0.2 x 0.2 cm) with ink. The margin is reinked and entirely submitted in E, for frozen section.
*FS/DX: NEGATIVE.
- (F) ANTERIOR FLOOR OF MOUTH, FROZEN, NEW MARGIN INKED - Received is a fresh pink-tan tissue fragment (1.5 x 0.2 x 0.2 cm) with ink on the margin. The margin is reinked and entirely submitted in F, for frozen section.
*FS/DX: NEGATIVE.
- (G) POSTERIOR FLOOR OF MOUTH, NEW MARGIN INKED - Received is a 1.4 x 0.3 x 0.3 cm portion of pink soft tissue that is oriented by the surgeon with ink designating the true margin. The true margin is reinked blue.
SECTION CODE: G, entire specimen, submitted en face, for frozen section diagnosis.
*FS/DX: NEGATIVE.
- (H) POSTERIOR TONGUE, NEW MARGIN INKED - Received is a 1.8 x 0.5 x 0.4 cm portion of pink soft tissue that is oriented by the surgeon with ink designating the true margin. The true margin is reinked blue.
SECTION CODE: H, entire specimen submitted en face, for frozen section diagnosis.
*FS/DX: NEGATIVE.
- (I) DEEP TONGUE MARGIN, NEW MARGIN INKED - Received is a 1.7 x 1.2 x 0.4 cm fragment of dark pink soft tissue that is oriented by the surgeon with ink designating the true margin. The true margin is reinked blue.
SECTION CODE: I, entire specimen, submitted en face, for frozen section diagnosis.
*FS/DX: NEGATIVE.
- (J) RIGHT NECK DISSECTION, LEVEL I A AND B - Received is a 5.5 x 5.0 x 2.0 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal seven possible lymph nodes ranging from 0.3 x 0.3 x 0.2 cm - 2.0 x 0.8 x 0.6 cm and a gland that measures 4.0 x 3.5 x 1.5 cm. Cut surfaces of the gland are tan, lobulated, and unremarkable.
SECTION CODE: J1, two possible lymph nodes; J2, two possible lymph nodes; J3, one possible lymph node, serially sectioned; J4, one possible lymph node, serially sectioned; J5, one possible lymph node, serially sectioned; J6, representative section of gland.
- (K) RIGHT NECK DISSECTION, LEVEL II - Received is a 4.3 x 4.2 x 1.0 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal sixteen possible lymph nodes ranging from 0.2 x 0.2 x 0.1 cm - 2.5 x 1.3 x 0.5 cm.
SECTION CODE: K1, two possible lymph nodes; K2, three possible lymph nodes; K3, three possible lymph nodes; K4,

[page 3 of 4]
M

Accession:
Specimen Date/Time:

three possible lymph nodes; K5, two possible lymph nodes; K6, one possible lymph node, serially sectioned; K7, K8, one possible lymph node, serially sectioned; K9, K10, one possible lymph node, serially sectioned.

(L) RIGHT NECK DISSECTION, LEVEL III - Received is a 3.2 x 2.5 x 0.8 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal seven possible lymph nodes ranging from 0.5 x 0.4 x 0.3 cm - 2.7 x 0.7 x 0.3 cm.

SECTION CODE: L1, two possible lymph nodes; L2, three possible lymph nodes; L3, one possible lymph node, serially sectioned; L4, one possible lymph node, serially sectioned. Entire specimen is submitted.

(M) RIGHT NECK, LEVEL IV - Received is a 3.4 x 3.0 x 0.7 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal nineteen possible lymph nodes ranging from 0.3 x 0.2 x 0.1 cm - 1.1 x 0.5 x 0.4 cm.

SECTION CODE: M1, two possible lymph nodes; M2, three possible lymph nodes; M3, three possible lymph nodes; M4, three possible lymph nodes; M5, three possible lymph nodes; M6, three possible lymph nodes; M7, two possible lymph nodes.

(N) MULTIPLE DENTAL EXTRACTION WITH BONE AND SOFT TISSUE - Received is a 7.0 x 1.5 x 1.0 cm aggregate of multiple teeth and tooth fragments. Gross only.

CLINICAL HISTORY

None given.

SNOMED CODES

T-53000, M-80703

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 4 of 4]
Accession:
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

COMMENT

The tumor is negative for high risk human papilloma virus (HPV) by in situ hybridization performed at

The tumor is negative for hybridization in the nuclei for any of the following genotypes contained in the probe cocktail: 16, 18, 31, 33, 35, 39, 45, 51, 52, 56, 58, and 66. The positive control was appropriate.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Division of Pathology and Laboratory Medicine

IHPAA Discrepancy		☒

9/9/12

Source: NCI Genomic Data Commons file 85525911-cca4-4eac-b853-ab1fb117d801 (TCGA-CV-A465.F0923ED1-8AB2-4A2F-A034-F48FE8B9A210.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).